Somatic mutation profile of tumor specimen TARGET-20-PATAUU-09A (aliquot TARGET-20-PATAUU-09A-01D) from TARGET case TARGET-20-PATAUU, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.2 years (6,295 days).
Specimen TARGET-20-PATAUU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d4f88cf-a319-4aa6-b84b-14d36056e262.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATAUU-14A (Bone Marrow Normal), aliquot TARGET-20-PATAUU-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9e82916-91c4-46eb-a1a6-95411325d9ac

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Frame Shift Ins 2, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>T p.D835Y | Missense Mutation (SNP) | VAF 98/353 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 26/182 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.692); catalogued as rs121913528, COSV55499283, COSV55796966; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 97/255 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs397507510, CD055729, CM021127, CM101143, COSV61004841, COSV61006072, COSV61006164; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CCND3 | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV104369101, COSV57827957; called by muse, varscan2
- ASXL2 | c.2751_2752insTG p.S918* | Frame Shift Ins (INS) | VAF 136/380 reads (36%) | called by mutect2, pindel, varscan2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 13/78 reads (17%) | called by pindel, varscan2
- GATA2 | c.591C>T p.S197= | Silent (SNP) | VAF 67/149 reads (45%) | called by muse, mutect2, varscan2
- RUNX1 | c.*1983C>T | 3'UTR (SNP) | VAF 34/247 reads (14%) | catalogued as rs1418715295; called by muse, mutect2, varscan2
